TCGA case TCGA-E1-5318 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/400b2fa3-baf7-4baa-99b4-88b9f25b5049

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 2,379 days (6.5 years).

Diagnoses (2)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.1 years (15,372 days); Year of diagnosis: 1997; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 31-90 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 385 days (1.1 years); Days to treatment end: 781 days (2.1 years); Number of cycles: 11; Treatment dose: 6,507 mg; Prescribed dose: 560; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 781 days (2.1 years); Days to treatment end: 824 days (2.3 years); Number of cycles: 1; Treatment dose: 1,650 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 824 days (2.3 years); Days to treatment end: 1,026 days (2.8 years); Number of cycles: 7; Treatment dose: 8,400 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 1,043 days (2.9 years); Days to treatment end: 1,231 days (3.4 years); Number of cycles: 1; Treatment dose: 8 Wafer; Prescribed dose: 8; Prescribed dose units: Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 1,258 days (3.4 years); Days to treatment end: 1,301 days (3.6 years); Treatment dose: 5,400 cGy; Course number: 5; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,590 days (4.4 years); Days to treatment end: 1,652 days (4.5 years); Number of cycles: 2; Treatment dose: 3,000 mg; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 1,655 days (4.5 years); Days to treatment end: 1,904 days (5.2 years); Number of cycles: 3; Treatment dose: 540 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 1,904 days (5.2 years); Days to treatment end: 1,971 days (5.4 years); Number of cycles: 2; Treatment dose: 280 mg; Prescribed dose: 82.5; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Celecoxib; Initial disease status: Progressive Disease; Days to treatment start: 1,980 days (5.4 years); Days to treatment end: 2,043 days (5.6 years); Number of cycles: 2; Treatment dose: 44,800 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 1,980 days (5.4 years); Days to treatment end: 2,043 days (5.6 years); Number of cycles: 2; Treatment dose: 5,600 mg; Prescribed dose: 100; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,023 days (5.5 years); Days to treatment end: 2,127 days (5.8 years); Number of cycles: 1; Treatment dose: 1,710 mg; Prescribed dose: 350; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 2,127 days (5.8 years); Days to treatment end: 2,211 days (6.1 years); Number of cycles: 2; Treatment dose: 3,400 mg; Prescribed dose: 260; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Initial disease status: Progressive Disease; Days to treatment start: 2,211 days (6.1 years); Days to treatment end: 2,267 days (6.2 years); Number of cycles: 2; Treatment dose: 6,720 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 2,211 days (6.1 years); Days to treatment end: 2,267 days (6.2 years); Number of cycles: 2; Treatment dose: 4,480 mg; Prescribed dose: 80; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 2,268 days (6.2 years); Days to treatment end: 2,335 days (6.4 years); Number of cycles: 2; Treatment dose: 280 mg; Prescribed dose: 82.5; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Oligodendroglioma, NOS). Age at diagnosis: 43.1 years (15,734 days); Days to diagnosis: 362 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 362 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 362 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 362 days; Karnofsky performance status: 100.
- Days to follow up: 2,379 days (6.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-5318-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-E1-5318-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-E1-5318-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-E1-5318-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 31 - 90 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No.
- Drug treatment 1: Regimen number: 7; Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 4; Pharmaceutical therapy drug name: Gliadel Wafers; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: Intum.
- Drug treatment 3: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 4: Regimen number: 10; Pharmaceutical therapy drug name: CPT-11; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 8; Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 6: Regimen number: 12; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 13; Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 2; Pharmaceutical therapy drug name: Temazolomide.
- Drug treatment 9: Regimen number: 9; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 10: Regimen number: 3.
- Drug treatment 11: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 12: Regimen number: 9; Pharmaceutical therapy drug name: Celebrex; Therapy regimen: Progression.
- Drug treatment 13: Regimen number: 9; Pharmaceutical therapy drug name: VP-16; Therapy regimen: Progression.
- Drug treatment 14: Regimen number: 12; Pharmaceutical therapy drug name: Tamoxiten; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome at TCGA followup: Stable Disease; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,379 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,379 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 362 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-5318-01A-01D-1466-01): tumor purity 0.78, ploidy 3.92, whole-genome doublings 1.
